Gene-level copy-number profile of tumor specimen ALCH-B47L-TTP1-A from ALCHEMIST case ALCH-B47L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.1 years (29,255 days).
Specimen ALCH-B47L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78bec877-e121-49c9-9b3a-68b993a3a5b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B47L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,281 have no estimate.
https://portal.gdc.cancer.gov/files/9d846e54-0020-4d30-a55f-86954dbfdcd7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 181; copy number 1: 3,953; copy number 2: 53,279; copy number 3: 700; copy number 4: 129; copy number 5: 38; copy number 6: 12; copy number 7: 21; copy number 8: 10; copy number 9: 1; copy number 10: 3; copy number 11: 2; copy number 12: 4; copy number 13: 2; copy number 15: 4; copy number 16: 1; copy number 24: 1; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): 165 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,748,095–112,748,475, 1 gene: NUTF2P4.
- chr1:241,957,767–241,959,062, 1 gene: BECN2.
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:89,906,757–89,916,052, 2 genes: IGKV3D-34, IGKV1D-33.
- chr2:90,100,236–90,115,402, 2 genes (within-gene range 0–1): IGKV1D-16, IGKV3D-15.
- chr2:90,309,230–91,621,421, 7 genes (within-gene range 0–2): AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:206,159,585–206,162,928, 5 genes (within-gene range 0–1): EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41.
- chr4:56,760,919–56,821,742, 6 genes: AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA.
- chr5:69,469,883–69,502,466, 3 genes (within-gene range 0–1): RPS27P14, AC145146.1, RN7SL616P.
- chr5:138,252,380–138,274,621, 2 genes: GFRA3, RPS27AP18.
- chr7:75,922,755–75,943,916, 2 genes: RPL7L1P3, SNORA14A.
- chr7:138,645,671–138,703,062, 3 genes (within-gene range 0–1): AC013429.1, AC020983.1, UQCRFS1P2.
- chr8:42,752,620–42,844,876, 3 genes: CHRNA6, THAP1, AC087533.1.
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.
- chr10:32,102,522–32,173,744, 4 genes: RPS4XP11, AL161932.2, AL161932.1, RNU7-22P.
- chr10:32,231,849–32,232,245, 1 gene: RPS24P13.
- chr10:34,875,210–34,875,422, 1 gene: SS18L2P1.
- chr10:92,272,147–92,272,250, 1 gene (within-gene range 0–1): Y_RNA.
- chr10:103,367,976–103,446,294, 4 genes: TAF5, ATP5MD, MIR1307, PDCD11.
- chr10:133,237,855–133,241,928, 1 gene: VENTX.
- chr10:133,295,187–133,295,977, 1 gene (within-gene range 0–2): AL360181.2.
- chr10:133,420,666–133,424,572, 1 gene (within-gene range 0–2): SPRN.
- chr12:122,395,542–122,400,857, 1 gene (within-gene range 0–1): CLIP1-AS1.
- chr12:123,707,602–123,708,386, 1 gene (within-gene range 0–1): AC117503.1.
- chr12:132,360,734–132,361,198, 1 gene: AC148477.6.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:18,555,677–18,602,129, 5 genes (within-gene range 0–1): CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12.
- chr14:63,567,958–63,665,593, 10 genes: AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3.
- chr14:63,734,697–63,736,505, 2 genes: EIF2S2P1, RNU7-116P.
- chr14:63,762,013–63,762,149, 1 gene: AL161670.1.
- chr14:104,821,201–104,823,718, 1 gene: LINC00638.
- chr15:50,702,266–50,765,709, 3 genes: SPPL2A, AC012100.3, AC012100.2.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:90,074,512–90,082,207, 2 genes (within-gene range 0–2): ZNF710-AS1, U7.
- chr16:46,469,341–46,575,094, 4 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr19:6,306,142–6,362,149, 2 genes (within-gene range 0–1): ACER1, AC011491.3.
- chr19:6,375,148–6,412,404, 6 genes (within-gene range 0–1): PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,680,538–9,129,752, 15 genes: CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,203,508–1,214,153, 2 genes, copy number 7–13: TNFRSF18, TNFRSF4.
- chr1:1,242,446–1,246,722, 1 gene, copy number 13: C1QTNF12.
- chr1:1,292,390–1,311,677, 3 genes, copy number 5–10 (within-gene range 2–10): ACAP3, MIR6726, PUSL1.
- chr1:1,324,756–1,328,896, 1 gene, copy number 7: CPTP.
- chr1:1,352,689–1,361,777, 1 gene, copy number 7: MXRA8.
- chr1:1,409,096–1,410,618, 1 gene, copy number 5: MRPL20-DT.
- chr1:1,430,539–1,442,882, 2 genes, copy number 6: LINC01770, VWA1.
- chr1:1,534,778–1,540,624, 1 gene, copy number 5: TMEM240.
- chr1:1,598,012–1,600,135, 1 gene, copy number 8: FNDC10.
- chr1:2,403,964–2,413,797, 1 gene, copy number 8 (within-gene range 3–8): PEX10.
- chr1:2,530,064–2,565,382, 3 genes, copy number 5–8 (within-gene range 3–8): AL139246.5, TNFRSF14-AS1, TNFRSF14.
- chr1:2,586,491–2,591,469, 1 gene, copy number 10 (within-gene range 3–10): PRXL2B.
- chr1:2,635,976–2,801,717, 3 genes, copy number 7 (within-gene range 3–7): TTC34, AC242022.2, AC242022.1.
- chr1:2,814,056–2,817,767, 2 genes, copy number 5: AL592464.3, AL592464.1.
- chr5:946,315–981,300, 2 genes, copy number 5–6: AC122719.1, AC122719.2.
- chr9:137,423,350–137,550,402, 5 genes, copy number 5 (within-gene range 2–5): NOXA1, ENTPD8, NSMF, MIR7114, PNPLA7.
- chr10:132,965,534–132,976,354, 1 gene, copy number 5: LINC01168.
- chr10:133,230,217–133,231,558, 1 gene, copy number 11: UTF1.
- chr10:133,246,478–133,247,891, 2 genes, copy number 5: MIR202HG, MIR202.
- chr10:133,262,420–133,276,868, 1 gene, copy number 8: ADAM8.
- chr10:133,430,394–133,431,318, 1 gene, copy number 6: OR6L2P.
- chr11:1,157,953–1,201,138, 1 gene, copy number 5: MUC5AC.
- chr11:1,389,899–1,462,689, 1 gene, copy number 5: BRSK2.
- chr11:1,554,051–1,572,271, 1 gene, copy number 5 (within-gene range 4–5): DUSP8.
- chr11:1,734,821–1,778,388, 5 genes, copy number 7–8 (within-gene range 3–8): AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.2.
- chr11:1,919,703–2,161,221, 11 genes, copy number 5–15: TNNT3, MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, AC132217.1, IGF2-AS, INS.
- chr14:104,769,349–104,804,712, 2 genes, copy number 7 (within-gene range 3–7): AKT1, ZBTB42.
- chr14:104,857,792–104,896,770, 2 genes, copy number 8–10: AL583810.1, CEP170B.
- chr14:105,486,317–105,499,575, 3 genes, copy number 6–12: CRIP1, AL928654.3, TEDC1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 12–35 (within-gene range 5–35): IGHA2, IGHE.
- chr16:769,119–769,443, 1 gene, copy number 15 (within-gene range 2–15): AL031258.1.
- chr16:788,046–800,737, 2 genes, copy number 7 (within-gene range 2–7): CHTF18, GNG13.
- chr16:1,963,745–1,964,095, 1 gene, copy number 7: AC005363.1.
- chr16:1,978,917–1,994,275, 4 genes, copy number 6 (within-gene range 4–6): NOXO1, GFER, AC005606.2, SYNGR3.
- chr16:88,803,789–88,866,660, 4 genes, copy number 5–6 (within-gene range 3–6): CDT1, APRT, TRAPPC2L, PABPN1L.
- chr17:81,303,771–81,309,248, 1 gene, copy number 11: LINC00482.
- chr19:851,014–856,247, 1 gene, copy number 5: ELANE.
- chr19:1,248,553–1,279,244, 4 genes, copy number 5–16: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:62,952,707–63,007,035, 2 genes, copy number 7–24: SLC17A9, BHLHE23.
- chr22:20,110,821–20,117,392, 3 genes, copy number 7 (within-gene range 2–7): AC006547.2, TRMT2A, MIR6816.

Autosomal genes at a single copy (total copy number 1): 3,775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
